Somatic mutation profile of tumor specimen TCGA-SG-A849-01A (aliquot TCGA-SG-A849-01A-11D-A351-09) from TCGA case TCGA-SG-A849, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 78.0 years (28,498 days).
Specimen TCGA-SG-A849-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ddded08-940d-4e40-b221-5603722bf2fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SG-A849-10A (Blood Derived Normal), aliquot TCGA-SG-A849-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b243fcb3-9984-4b84-b52d-fa6a52a0e701

The open-access MAF lists 52 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 35, Silent 12, Nonsense Mutation 3, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL8 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs267598220, COSV64861450; called by muse, mutect2, varscan2
- ADH7 | c.515T>C p.I172T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs757888348, COSV99265380; called by muse, mutect2, varscan2
- ASTN2 | c.2630T>A p.F877Y (on ENST00000313400 / NM_001365069.1; = p.F826Y on NM_014010.5) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100529157; called by muse, mutect2, varscan2
- BID | c.608_619del p.K203_A206del (on ENST00000317361 / NM_197966.2; = p.K157_A160del on NM_001196.4) | In Frame Del (DEL) | VAF 6/62 reads (10%) | catalogued as rs759487323; called by mutect2, pindel
- BIRC6 | c.9499G>T p.G3167C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.915); catalogued as COSV101428514; called by muse, mutect2, varscan2
- CDKL2 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as rs1158297639, COSV56732728; called by muse, mutect2, varscan2
- CFAP91 | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs556802557, COSV99847345; called by muse, varscan2
- CLTCL1 | c.2743C>G p.H915D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99595525; called by muse, mutect2, varscan2
- CSF2RA | c.841T>C p.Y281H | Missense Mutation (SNP) | VAF 24/251 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as COSV100817872; called by muse, mutect2, varscan2
- DDI2 | c.139-2A>G p.X47_splice | Splice Site (SNP) | VAF 5/72 reads (7%) | catalogued as COSV100197800; called by muse, mutect2
- DNMT1 | c.3293A>T p.D1098V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as COSV100532785; called by muse, mutect2, varscan2
- GRAP2 | c.389A>T p.D130V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100703078; called by muse, mutect2, varscan2
- GRIK1 | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs762478078, COSV100517464; called by muse, mutect2, varscan2
- HECTD4 | c.8495C>T p.A2832V | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV101108121; called by muse, mutect2, varscan2
- IL23R | c.1250A>G p.E417G | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV100724852; called by muse, mutect2, varscan2
- JARID2 | c.1735G>T p.A579S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.107); catalogued as rs752536884, COSV100522099; called by muse, mutect2, varscan2
- KCNIP4 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100749619; called by muse, mutect2, varscan2
- KIF6 | c.1973A>C p.K658T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99759899; called by mutect2, varscan2
- KLHDC7B | c.1507G>A p.G503S (on ENST00000395676; = p.G1144S on NM_138433.5) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV67464376; called by muse, mutect2, varscan2
- LMAN1L | c.392G>A p.W131* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as COSV100547780; called by muse, mutect2, varscan2
- LRP1 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1178852705, COSV99676623; called by muse, mutect2
- LRRC17 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99978554; called by muse, mutect2, varscan2
- MARK3 | c.2008A>T p.M670L (on ENST00000429436 / NM_001128918.3; = p.M646L on NM_002376.6) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99358536; called by muse, mutect2, varscan2
- OR2G3 | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60681296; called by muse, mutect2, varscan2
- OR5F1 | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99558813; called by muse, mutect2
- PEG3 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs763208406, COSV55632441; called by muse, mutect2, varscan2
- PTPRB | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV99718321; called by muse, mutect2, varscan2
- RBM27 | c.1838A>G p.N613S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV99506436; called by muse, mutect2, varscan2
- RDH10 | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99536410; called by muse, mutect2, varscan2
- RPH3A | c.550C>T p.P184S (on ENST00000389385 / NM_001143854.2; = p.P180S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs1308329860, COSV101231866; called by muse, mutect2, varscan2
- RTEL1 | c.1997T>G p.M666R | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs1421096557, COSV100542614; called by muse, mutect2, varscan2
- SELP | c.1058A>G p.E353G | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as COSV99740634; called by muse, mutect2, varscan2
- SLC12A4 | c.891G>C p.K297N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV100312007; called by muse, mutect2, varscan2
- SLC35D3 | c.891C>A p.Y297* | Nonsense Mutation (SNP) | VAF 3/34 reads (9%) | catalogued as COSV100090646; called by muse, mutect2
- TBC1D9 | c.2893A>G p.T965A | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101464380; called by mutect2, varscan2
- TPX2 | c.1319G>T p.R440I | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100301935; called by muse, mutect2, varscan2
- USP6 | c.2734C>T p.R912W | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as rs148034086; called by muse, mutect2, varscan2
- VAMP7 | c.139C>A p.H47N | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99387948; called by muse, mutect2, varscan2
- ZFX | c.601C>A p.Q201K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV100457924; called by muse, mutect2, varscan2
- ZNF677 | c.220A>G p.K74E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV61719536; called by muse, mutect2, varscan2
- DYSF | c.5649C>A p.V1883= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV99249283; called by muse, mutect2, varscan2
- F9 | c.36A>G p.P12= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99496768; called by muse, mutect2, varscan2
- FAT3 | c.13191T>A p.G4397= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99968334; called by muse, mutect2, varscan2
- FGFR4 | c.2092C>T p.L698= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs745342988, COSV99450520; called by muse, mutect2, varscan2
- FOLH1 | c.1164T>G p.P388= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV99923593; called by muse, mutect2, varscan2
- GRM3 | c.546G>A p.S182= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs1332779996, COSV64473049; called by muse, mutect2, varscan2
- LPO | c.1512C>T p.V504= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs1309505404, COSV99229142; called by muse, mutect2
- MC3R | c.549G>A p.S183= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1411606418, COSV54763790; called by mutect2, varscan2
- PIK3AP1 | c.1599A>T p.P533= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100226053; called by muse, mutect2
- PUM3 | c.504G>T p.G168= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV101193213; called by muse, mutect2, varscan2
- TRPM6 | c.3705G>A p.E1235= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100666715; called by muse, mutect2, varscan2
- ZNF280D | c.9C>T p.D3= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV99974831; called by muse, mutect2, varscan2
